Somatic mutation profile of tumor specimen TCGA-EM-A3SY-01A (aliquot TCGA-EM-A3SY-01A-11D-A22Z-08) from TCGA case TCGA-EM-A3SY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.9 years (13,461 days).
Specimen TCGA-EM-A3SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 229dc395-40b8-4673-8d1f-453e90860f18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3SY-10A (Blood Derived Normal), aliquot TCGA-EM-A3SY-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97c07695-1d8d-4e40-a483-85d3b1667e49

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, In Frame Del 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LYST | c.4493A>T p.K1498M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV101089724; called by muse, mutect2, varscan2
- OTUD7A | c.1331A>G p.Y444C (on ENST00000307050 / NM_001382637.1; = p.Y437C on NM_130901.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100192657; called by muse, mutect2
- RPTOR | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100156441; called by muse, mutect2, varscan2
- SCN5A | c.5216G>A p.R1739Q (on ENST00000333535 / NM_198056.3; = p.R1738Q on NM_000335.5) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs200217157, COSV61116728, COSV61119074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX19 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs181345241, COSV99773189; called by muse, mutect2, varscan2
- ZEB2 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248212141, COSV100356255; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRWD3 | c.3100del p.V1035Cfs*23 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, pindel, varscan2
- GPRC5D | c.805_813del p.C269_Q271del | In Frame Del (DEL) | VAF 12/138 reads (9%) | called by mutect2, pindel
- OR5B17 | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ZNF544 | c.429_431del p.M143_V144delinsI | In Frame Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- MGAT4A | c.1164C>T p.I388= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV53846148; called by muse, mutect2, varscan2
